CCDI case PBCGEI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/e3344eb1-867f-4e6c-b2ae-a63a73c0144d

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.4 years (3,790 days).

Biospecimens (4 samples)
- Samples 0DRGER, 0DRGF3 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRIWE: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DRQSX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
